Somatic mutation profile of tumor specimen MP2PRT-PARUNF-TBP1-A (aliquot MP2PRT-PARUNF-TBP1-A-1-0-D-A83O-36) from MP2PRT case MP2PRT-PARUNF, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.5 years (1,638 days).
Specimen MP2PRT-PARUNF-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3e65cce6-c707-49f7-a448-963edebb55a4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARUNF-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARUNF-NB1-A-1-0-D-A83O-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3c195551-14d4-4616-a743-d3bf4c108bd2

The open-access MAF lists 21 somatic variants for this specimen: 13 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 13, Silent 8.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- F9 | c.1025C>T p.T342M | Missense Mutation (SNP) | VAF 118/259 reads (46%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.993); catalogued as rs137852254, CM940624, CM940625, COSV54382299; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AVPR1A | c.986C>G p.T329S | Missense Mutation (SNP) | VAF 82/186 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.009); catalogued as COSV100146901; called by muse, mutect2, varscan2
- CD163L1 | c.808C>T p.R270C | Missense Mutation (SNP) | VAF 66/176 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs143343430; called by muse, mutect2, varscan2
- CHD4 | c.3443A>C p.H1148P (on ENST00000357008 / NM_001363606.2; = p.H1161P on NM_001273.5) | Missense Mutation (SNP) | VAF 10/206 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58902003; called by muse, mutect2
- GDAP1L1 | c.836G>A p.R279H | Missense Mutation (SNP) | VAF 122/268 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755646369, COSV61158174; called by muse, mutect2, varscan2
- MCM3AP | c.1862G>A p.R621Q | Missense Mutation (SNP) | VAF 57/284 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.431); catalogued as rs761589648, COSV99386332; called by muse, mutect2, varscan2
- MTRNR2L10 | c.59C>T p.A20V | Missense Mutation (SNP) | VAF 100/249 reads (40%) | PolyPhen benign (0); catalogued as rs1489773728; called by muse, mutect2, varscan2
- OR2M2 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 113/269 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.035); catalogued as rs142698993; called by muse, mutect2, varscan2
- PCDHA9 | c.1504C>T p.R502C | Missense Mutation (SNP) | VAF 277/568 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); catalogued as rs1554143600; called by muse, mutect2, varscan2
- PCDHGA1 | c.1696G>A p.A566T | Missense Mutation (SNP) | VAF 137/289 reads (47%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0.01); catalogued as rs776076044, COSV65294924, COSV65295117, COSV65297635; called by muse, mutect2, varscan2
- GRIN3B | c.2930C>G p.A977G | Missense Mutation (SNP) | VAF 232/561 reads (41%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, varscan2
- LBR | c.1298A>G p.D433G | Missense Mutation (SNP) | VAF 62/71 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UNC79 | c.3109C>T p.L1037F (on ENST00000393151 / NM_001346218.2; = p.L860F on NM_020818.5) | Missense Mutation (SNP) | VAF 120/397 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.296); called by muse, mutect2, varscan2
- ABCA9 | c.2778T>C p.I926= | Silent (SNP) | VAF 68/244 reads (28%) | called by muse, mutect2, varscan2
- COL6A2 | c.2784C>T p.I928= | Silent (SNP) | VAF 169/745 reads (23%) | catalogued as rs199501232; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- ESPN | c.2166C>T p.P722= | Silent (SNP) | VAF 200/437 reads (46%) | catalogued as rs754894303, COSV100911552; called by muse, mutect2, varscan2
- FOXN4 | c.135G>A p.S45= | Silent (SNP) | VAF 218/422 reads (52%) | catalogued as rs1465986094, COSV54493424; called by muse, mutect2, varscan2
- GLI2 | c.111G>T p.V37= | Silent (SNP) | VAF 136/314 reads (43%) | called by muse, mutect2, varscan2
- LRRC45 | c.840G>A p.S280= | Silent (SNP) | VAF 86/307 reads (28%) | catalogued as rs138761482; called by muse, mutect2, varscan2
- OR2A7 | c.201C>T p.V67= | Silent (SNP) | VAF 101/465 reads (22%) | called by muse, varscan2
- TNIP3 | c.936C>T p.H312= | Silent (SNP) | VAF 70/307 reads (23%) | called by muse, mutect2, varscan2
